Somatic mutation profile of tumor specimen TCGA-V1-A9O9-01A (aliquot TCGA-V1-A9O9-01A-11D-A41K-08) from TCGA case TCGA-V1-A9O9, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9O9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad5fc968-209f-46b2-ae7a-23d4adf68ace.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9O9-10A (Blood Derived Normal), aliquot TCGA-V1-A9O9-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e39174af-fe0a-454c-97f5-4968ace50b72

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 15, Silent 7, Frame Shift Del 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR3 | c.6878G>T p.G2293V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.139); catalogued as rs1292294702, COSV99372811; called by muse, mutect2, varscan2
- DCAF12L1 | c.858C>A p.F286L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV64421560, COSV64422655; called by muse, mutect2, varscan2
- EMC2 | c.631T>G p.S211A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99623942; called by muse, mutect2, varscan2
- FLNC | c.6308C>A p.T2103N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100367709, COSV57967260; called by muse, mutect2, varscan2
- FREM2 | c.7579C>A p.R2527S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as COSV54848659, COSV99747301; called by muse, mutect2, varscan2
- HNRNPR | c.1780del p.W594Gfs*46 | Frame Shift Del (DEL) | VAF 21/159 reads (13%) | catalogued as COSV100164493; called by mutect2, pindel, varscan2
- LARP4B | c.1256G>T p.R419L | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776303473, COSV100295138; called by muse, mutect2, varscan2
- LRIF1 | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs377597305; called by muse, mutect2, varscan2
- MAN2A2 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100847776; called by muse, mutect2, varscan2
- NRIP1 | c.679del p.T227Qfs*4 | Frame Shift Del (DEL) | VAF 35/148 reads (24%) | catalogued as COSV59657162; called by mutect2, pindel, varscan2
- OR5T2 | c.40T>A p.L14M | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.276); catalogued as COSV100506847; called by muse, mutect2, varscan2
- OR5W2 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100747557; called by muse, mutect2, varscan2
- OSBPL11 | c.801C>G p.C267W | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99954019; called by muse, mutect2
- PIK3CG | c.2363A>G p.D788G | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100782633; called by muse, mutect2, varscan2
- PPP1R8 | c.297T>G p.I99M | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.194); catalogued as COSV99360852; called by muse, mutect2, varscan2
- RPP30 | c.550-1G>C p.X184_splice | Splice Site (SNP) | VAF 9/160 reads (6%) | catalogued as COSV99520678; called by muse, mutect2
- UBE2F | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs756699586, COSV99800141; called by muse, mutect2, varscan2
- ZMYND19 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs779910825, COSV53812243; called by muse, mutect2, varscan2
- KIDINS220 | c.3001_3011+1del p.X1001_splice | Splice Site (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- ZSCAN10 | c.845del p.G282Afs*18 (on ENST00000252463; = p.G337Afs*18 on NM_032805.3) | Frame Shift Del (DEL) | VAF 9/100 reads (9%) | called by mutect2, varscan2
- ARPP21 | c.1989C>T p.N663= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs550779254, COSV51791188; called by muse, mutect2, varscan2
- ENAM | c.976A>C p.R326= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV101252956; called by muse, mutect2, varscan2
- FBN1 | c.3906A>G p.S1302= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as rs756186103, COSV100354154; called by muse, mutect2, varscan2
- IFNA14 | c.429G>A p.V143= | Silent (SNP) | VAF 78/324 reads (24%) | catalogued as rs1455121025, COSV101207300; called by muse, mutect2, varscan2
- KIF14 | c.729G>A p.K243= | Silent (SNP) | VAF 8/197 reads (4%) | catalogued as COSV100950667; called by muse, mutect2
- RNF213 | c.2799C>T p.V933= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV100173172; called by muse, varscan2
- SLC38A9 | c.72T>A p.P24= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs1452633512, COSV100591282; called by muse, mutect2, varscan2
